Somatic mutation profile of tumor specimen TCGA-D6-A6EN-01A (aliquot TCGA-D6-A6EN-01A-11D-A31L-08) from TCGA case TCGA-D6-A6EN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.0 years (26,294 days).
Specimen TCGA-D6-A6EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4515aa57-5caa-4583-96c6-8a16c86850ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EN-10A (Blood Derived Normal), aliquot TCGA-D6-A6EN-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bb6d3d1-1100-4eba-a2fc-b9dbc11371fa

The open-access MAF lists 113 somatic variants for this specimen: 79 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 31, Nonsense Mutation 9, Frame Shift Del 4, Frame Shift Ins 4, Splice Region 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs121913496, COSV54236743, COSV54239883, COSV54242016; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFM | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV56919198, COSV99888811; called by muse, mutect2
- AP2A2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs772196174, COSV59959829; called by muse, mutect2, varscan2
- ATE1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1346893307, COSV99817127; called by muse, mutect2, varscan2
- CASP8 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51850167, COSV99965200; called by muse, mutect2, varscan2
- CCL25 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99495158; called by muse, mutect2, varscan2
- CDH10 | c.1626T>C p.D542= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100051428; called by muse, mutect2, varscan2
- CDKN2A | c.157_158dup p.M53Ifs*2 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | catalogued as COSV58720156; called by mutect2, pindel, varscan2
- CENPF | c.8696G>A p.G2899E | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV100871691; called by muse, mutect2, varscan2
- CEP250 | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100698928; called by muse, mutect2
- CERT1 | c.1538G>A p.S513N (on ENST00000405807 / NM_001130105.1; = p.S385N on NM_005713.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as rs747847141, COSV99783248; called by muse, mutect2, varscan2
- CLCA4 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99760489; called by muse, mutect2, varscan2
- COL1A2 | c.3630C>A p.N1210K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99799707; called by muse, mutect2, varscan2
- DESI1 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1195588861, COSV99610938; called by muse, mutect2, varscan2
- DMXL2 | c.8665G>A p.G2889R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.115); catalogued as rs1382762007, COSV99196365; called by muse, mutect2, varscan2
- DNAH9 | c.7100A>C p.K2367T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99305846; called by muse, mutect2, varscan2
- DNAJC5B | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99395621; called by muse, mutect2
- FAT1 | c.11704C>T p.Q3902* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV71672040, COSV71673132; called by muse, mutect2, varscan2
- FNBP4 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99771659; called by muse, mutect2, varscan2
- H2AC8 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV99773229; called by muse, mutect2, varscan2
- H3C2 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV52518592, COSV52519945, COSV99451484; called by muse, mutect2, varscan2
- HSPA14 | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101000667; called by muse, mutect2, varscan2
- IRF2 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101165815; called by muse, mutect2, varscan2
- IRF4 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV66705115; called by muse, mutect2, varscan2
- KBTBD12 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as rs761700076, COSV100675430; called by muse, mutect2, varscan2
- KLHL4 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99058277; called by muse, mutect2, varscan2
- L3MBTL4 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99528968; called by muse, mutect2, varscan2
- LACTB2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs770992611, COSV52568802; called by muse, mutect2, varscan2
- LRWD1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52961644, COSV99479334; called by muse, mutect2, varscan2
- MCC | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs149948216; called by muse, mutect2
- NALCN | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); catalogued as COSV99215159; called by muse, mutect2, varscan2
- NAXE | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100963889; called by muse, mutect2, varscan2
- NEB | c.5924C>T p.S1975L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772257977, COSV99422796; called by muse, mutect2, varscan2
- NEK10 | c.3377T>C p.I1126T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs111622636, COSV99835180; called by muse, mutect2, varscan2
- NEUROD4 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV99669919; called by muse, mutect2, varscan2
- NEXMIF | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99280808; called by muse, mutect2, varscan2
- NINL | c.3900G>T p.M1300I | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.198); catalogued as COSV54003046, COSV99625339; called by muse, mutect2, varscan2
- NOTCH1 | c.981G>C p.W327C | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53036206; called by muse, mutect2, varscan2
- NPAS3 | c.1898C>T p.P633L (on ENST00000356141 / NM_001164749.2; = p.P601L on NM_022123.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV100640219, COSV60833781; called by muse, mutect2, varscan2
- OR2AG1 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs112661648, COSV100264867; called by muse, mutect2, varscan2
- PCCA | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV100886838; called by muse, mutect2, varscan2
- PCDHGA12 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99340076; called by muse, mutect2, varscan2
- PCDHGB7 | c.1576C>A p.R526S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99538224; called by muse, mutect2, varscan2
- PEG3 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs368105379; called by muse, mutect2, varscan2
- POU6F2 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101302660; called by muse, mutect2, varscan2
- PRUNE2 | c.7571C>A p.P2524H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100944556; called by muse, mutect2
- PTPN14 | c.1807C>T p.Q603* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs759810971, COSV100872576; called by mutect2, varscan2
- RBMXL2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs373944375; called by muse, mutect2, varscan2
- RPS6KA3 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV101084383; called by muse, mutect2, varscan2
- RYR1 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs751849934, COSV100615713; called by muse, mutect2, varscan2
- SERPINA7 | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100568323, COSV100568453; called by muse, mutect2, varscan2
- SHB | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100891746; called by muse, mutect2, varscan2
- SLC4A5 | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs770652020, COSV61035171; called by muse, mutect2, varscan2
- SLITRK2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100157630; called by muse, mutect2, varscan2
- STIMATE | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs760255234, COSV100753756, COSV61890708; called by muse, mutect2, varscan2
- TAF1L | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs528038779, COSV54261079; called by muse, mutect2, varscan2
- TMOD1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs767885123, COSV52251823; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4292G>C p.G1431A | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs371891458; called by muse, mutect2, varscan2
- TOMM20 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV100783959; called by muse, mutect2, varscan2
- TRIP12 | c.4889C>A p.P1630H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99390241; called by muse, mutect2, varscan2
- TTBK1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99444545; called by muse, mutect2, varscan2
- UBALD1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99364257; called by muse, mutect2, varscan2
- USP6 | c.2829T>A p.R943= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100003956; called by muse, varscan2
- VIRMA | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52589461; called by muse, mutect2, varscan2
- WDR59 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as rs779078769, COSV50935278; called by muse, mutect2, varscan2
- ZNF160 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100762332; called by muse, mutect2, varscan2
- ZNF608 | c.1532A>G p.N511S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as COSV100101648; called by muse, mutect2, varscan2
- ZNF629 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1230413636, COSV99354794; called by muse, mutect2, varscan2
- AJUBA | c.1015dup p.I339Nfs*50 | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- BCL9L | c.2790dup p.H931Afs*8 | Frame Shift Ins (INS) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- EPHA2 | c.602_616del p.C201_Q206delins* | Nonsense Mutation (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- FAT1 | c.7687del p.V2563* | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- IGHV4-59 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- KMT2B | c.4222dup p.A1408Gfs*270 | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- NES | c.4390_4393del p.V1467Pfs*6 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- STAB1 | c.6027_6028del p.A2010Sfs*20 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by pindel, varscan2
- ZNF594 | c.148del p.S50Afs*3 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD29 | c.366C>T p.Y122= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs778667200, COSV52424900, COSV99409157; called by muse, mutect2, varscan2
- APBA1 | c.696C>T p.G232= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1328521486, COSV99596063; called by muse, mutect2, varscan2
- ATXN10 | c.834C>T p.T278= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99426343; called by muse, mutect2, varscan2
- AURKC | c.903G>T p.L301= (on ENST00000302804 / NM_001015878.2; = p.L267= on NM_003160.3) | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs140410966; called by muse, mutect2, varscan2
- BCL3 | c.462G>A p.L154= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1188749991, COSV99378131; called by muse, mutect2, varscan2
- BICD2 | c.135G>A p.E45= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1309880043, COSV100794104; called by muse, mutect2
- BOLL | c.54G>A p.L18= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV99987080; called by muse, mutect2, varscan2
- C5orf34 | c.294C>T p.F98= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100175457; called by muse, mutect2, varscan2
- C6 | c.1929G>T p.G643= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99667077; called by muse, mutect2, varscan2
- CGNL1 | c.3426C>T p.S1142= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs145520145; called by muse, varscan2
- CIZ1 | c.849G>A p.P283= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs370276550; called by muse, mutect2, varscan2
- DCAF12L2 | c.39G>T p.A13= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs745912706, COSV100758604, COSV63581893; called by muse, mutect2, varscan2
- GJB3 | c.417C>T p.L139= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV100974005; called by muse, mutect2, varscan2
- GRHL3 | c.480G>A p.V160= (on ENST00000350501 / NM_198174.3; = p.V165= on NM_021180.3) | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as rs773199434, COSV99359362; called by muse, mutect2, varscan2
- ITPKC | c.907T>C p.L303= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99648724; called by muse, mutect2, varscan2
- NCKAP5 | c.1374G>C p.G458= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100492048, COSV100494722; called by muse, mutect2, varscan2
- OPRPN | c.546C>T p.I182= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV101271089; called by muse, mutect2, varscan2
- OR4X2 | c.450A>G p.A150= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as COSV100183238; called by muse, mutect2, varscan2
- OSBPL5 | c.2550G>C p.P850= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99720385; called by muse, mutect2, varscan2
- PCDHA11 | c.1947G>A p.L649= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100250399; called by muse, mutect2, varscan2
- PDZD2 | c.630G>A p.A210= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs774032258, COSV56850838; called by muse, mutect2, varscan2
- PHOX2B | c.405C>T p.I135= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs147497096; called by muse, mutect2, varscan2
- RMND5B | c.270C>A p.G90= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100523260; called by muse, mutect2, varscan2
- SNX13 | c.2853G>A p.A951= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs184459414; called by muse, mutect2, varscan2
- SPAG17 | c.6363G>A p.L2121= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60471024; called by muse, mutect2, varscan2
- TAS2R13 | c.468G>A p.L156= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101183739; called by muse, mutect2, varscan2
- TEX15 | c.7353G>A p.K2451= (on ENST00000256246; = p.K2834= on NM_001350162.2) | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV99821343; called by muse, mutect2, varscan2
- TNK2 | c.1350G>A p.S450= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs112025939, COSV100361307; called by muse, mutect2, varscan2
- TNXB | c.8658C>T p.A2886= (on ENST00000647633; = p.A2639= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100926313; called by muse, mutect2, varscan2
- UNC79 | c.3633C>A p.I1211= (on ENST00000393151 / NM_001346218.2; = p.I1034= on NM_020818.5) | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99827838; called by muse, mutect2, varscan2
- VAPA | c.261G>A p.P87= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1001488655, COSV100486074, COSV61297182; called by muse, mutect2
- ITPR2 | c.525+1070A>T | Intron (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99659313; called by muse, mutect2
- NDRG3 | c.93+6508C>T | Intron (SNP) | VAF 5/30 reads (17%) | catalogued as rs1265123228; called by muse, mutect2, varscan2
- RPP38 | chr10:15096579 C>G | 5'Flank (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
